TCGA case TCGA-DU-A76K — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/30bf5895-0671-4fb1-a96d-857847fcf7b0

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 86 years; Vital status: Dead; Days to death: 347 days.

Diagnoses (2)
1. Oligodendroglioma, NOS (the primary disease): ICD-O-3 morphology code: 9450/3; ICD-10 code: C71.0; Tissue or organ of origin: Cerebrum; Site of resection or biopsy: Nervous system, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 87.0 years (31,776 days); Year of diagnosis: 1999; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; First symptom longest duration: >=181 Days; First symptom prior to diagnosis: Headaches; Sites of involvement: Brain, Parietal.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 34 days; Days to treatment end: 82 days; Treatment dose: 59 Gy; Treatment outcome: Stable Disease; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 236 days; Days to treatment end: 269 days; Treatment outcome: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis.
2. Recurrence of diagnosis 1 (Oligodendroglioma, NOS). Age at diagnosis: 87.6 years (31,979 days); Days to diagnosis: 203 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 203 days; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS.

Follow-up (2 entries)
- Day 203 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 203 days.
- Days to follow up: 347 days; Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Headache.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DU-A76K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 340 mg.
  Slide TCGA-DU-A76K-01A-01-TS1: Section location: Top; Percent tumor cells: 10; Percent tumor nuclei: 75; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 85; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DU-A76K-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DU-A76K-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Oligodendroglioma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: No; Tumor status: With tumor; Tumor site: Supratentorial, Parietal Lobe; Supratentorial localization: Not listed in Medical Record; History seizures: No; History headaches: Yes; Symp changes mental status: No; Symp changes visual: No; Symp changes sensory: No; Symp changes motor movement: No; First symptom longest duration: > 181 Days; Idh1 mutation test indicator: No.
- Drug treatment: Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 347 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 347 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 203 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DU-A76K-01A-11D-A33S-01): tumor purity 0.61, ploidy 2, whole-genome doublings 0.
